Somatic mutation profile of tumor specimen ASCProject_0134_T1_WES (aliquot ASCProject_0134_T1_WES_1) from CMI case ASCProject_0134, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Skin of scalp and neck; Age at diagnosis: 62.8 years (22,935 days).
Specimen ASCProject_0134_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Scalp; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ff6682c-21f4-45aa-8fdd-e7930630822c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0134_SALIVA (Saliva), aliquot ASCProject_0134_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/682974b9-2b0b-48f2-8b45-ca80688f6d1d

The open-access MAF lists 237 somatic variants for this specimen: 153 protein-altering or splice-affecting, 58 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 58, Intron 12, Splice Region 5, Nonsense Mutation 5, 5'Flank 4, Frame Shift Del 3, RNA 3, 5'UTR 3, 3'UTR 2, Splice Site 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPGRIP1 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs565837539, CM1312225, COSV52845281; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.838A>G p.R280G | Missense Mutation (SNP) | VAF 277/319 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753660142, COSV52662754, COSV52708728, COSV52851287; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 131/300 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV55966863, COSV99714182; called by muse, mutect2, varscan2
- AFF3 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485483467; called by muse, mutect2, varscan2
- AIRE | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs200540137; called by muse, mutect2, varscan2
- ANAPC7 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466099904; called by muse, mutect2, varscan2
- BAAT | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192662506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C7orf31 | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs779518121; called by muse, mutect2, varscan2
- CFAP43 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs780370047, COSV53380099; called by muse, mutect2, varscan2
- CFAP45 | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.631); catalogued as rs199660398; called by muse, mutect2, varscan2
- CHRNA10 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV51702760; called by muse, mutect2, varscan2
- COL19A1 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59573948; called by muse, mutect2, varscan2
- COL4A1 | c.4876G>A p.A1626T | Missense Mutation (SNP) | VAF 98/465 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs765269741; called by muse, mutect2, varscan2
- DST | c.3278C>T p.P1093L (on ENST00000361203 / NM_001374722.1; = p.P767L on NM_001723.6) | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs778194334, COSV55037410; called by muse, mutect2, varscan2
- DTX3L | c.1887del p.F630Lfs*5 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as COSV56145925; called by mutect2, pindel, varscan2
- DTX4 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs61735920; called by muse, mutect2, varscan2
- EHMT2 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs772988696; called by muse, mutect2, varscan2
- EPHA3 | c.2387T>A p.I796K | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60706263, COSV60727761; called by muse, mutect2, varscan2
- EPS8L2 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs1449758656, COSV100585257; called by muse, mutect2, varscan2
- FAM135B | c.3439G>A p.G1147S | Missense Mutation (SNP) | VAF 70/301 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424442; called by muse, mutect2, varscan2
- FAM81B | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV51981627; called by muse, mutect2, varscan2
- FATE1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs748489127, COSV64848901; called by muse, mutect2, varscan2
- FBF1 | c.1793G>A p.R598Q (on ENST00000586717; = p.R612Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as rs758649435; called by muse, mutect2, varscan2
- FOXA1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV51644485; called by muse, mutect2, varscan2
- GGT7 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 107/237 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.264); catalogued as rs1171478210, COSV60540401; called by muse, mutect2, varscan2
- GHR | c.612G>A p.W204* | Nonsense Mutation (SNP) | VAF 48/128 reads (38%) | catalogued as COSV50109797; called by muse, mutect2, varscan2
- GRIA1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV53616897, COSV99599071; called by muse, varscan2
- HINFP | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771880097, COSV63431823; called by muse, mutect2, varscan2
- HRNR | c.2272G>A p.G758S | Missense Mutation (SNP) | VAF 120/259 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.068); catalogued as rs1274470104; called by muse, mutect2, varscan2
- HSPG2 | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65974950; called by muse, mutect2, varscan2
- IGKV1D-42 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as rs757241359; called by muse, mutect2, varscan2
- IGSF1 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as rs201712796, COSV63836956; called by muse, mutect2, varscan2
- IQSEC3 | c.1435G>A p.G479R (on ENST00000538872 / NM_001170738.2; = p.G176R on NM_015232.1) | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs782072943; called by mutect2, varscan2
- KNL1 | c.6581C>G p.S2194C (on ENST00000346991 / NM_170589.5; = p.S2168C on NM_144508.5) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61152057; called by muse, mutect2, varscan2
- KRT2 | c.957G>A p.A319= | Splice Region (SNP) | VAF 18/173 reads (10%) | catalogued as rs777533202; called by muse, mutect2
- LRRIQ1 | c.4625T>A p.I1542N | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775724645, COSV67829471; called by muse, mutect2, varscan2
- MATN2 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.893); catalogued as rs752673896, COSV54714418; called by muse, mutect2, varscan2
- MEF2D | c.606G>A p.A202= | Splice Region (SNP) | VAF 55/243 reads (23%) | catalogued as rs763029801, COSV61730080; called by mutect2, varscan2
- MTNR1B | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as rs565670988, CM121604, COSV57068231; called by muse, mutect2, varscan2
- MTOR | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.946); catalogued as COSV63875494; called by muse, mutect2, varscan2
- MTUS2 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV101462423; called by muse, mutect2
- MYH3 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1407060765; called by muse, mutect2, varscan2
- MYO18B | c.5873C>T p.S1958F | Missense Mutation (SNP) | VAF 163/243 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1444704245; called by muse, mutect2, varscan2
- NPHP3 | c.3032C>G p.A1011G | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs202145723; called by muse, mutect2, varscan2
- PCDHGA2 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1423721423, COSV53981061; called by muse, mutect2, varscan2
- PHF2 | c.1972G>A p.V658M | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs915369911; called by muse, mutect2
- PTPN9 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60723825; called by muse, mutect2, varscan2
- RASL10B | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs587776188; called by muse, varscan2
- RXFP2 | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV53633477; called by muse, mutect2, varscan2
- RYR2 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63675463; called by mutect2, varscan2
- SIX3 | c.425C>G p.T142R | Missense Mutation (SNP) | VAF 81/325 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV53228267; called by muse, mutect2, varscan2
- SLC5A8 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867168951, COSV101610512, COSV73310407; called by muse, mutect2, varscan2
- SLX4 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 126/145 reads (87%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs199929086; called by muse, mutect2, varscan2
- SPAG16 | c.1132G>T p.V378L | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV59070887, COSV59133810; called by muse, mutect2, varscan2
- TBX10 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226140206; called by muse, mutect2, varscan2
- TBX20 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 119/261 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101282370, COSV68782525; called by muse, mutect2, varscan2
- TDO2 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs750482663; called by muse, mutect2, varscan2
- TMCC3 | c.971A>G p.Q324R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV99705668; called by mutect2, varscan2
- USH2A | c.10286G>A p.R3429K | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV56354589; called by muse, mutect2, varscan2
- WFIKKN2 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs748492095; called by muse, mutect2, varscan2
- ZNF674 | c.490A>G p.R164G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs200601841; called by muse, mutect2
- ABCA8 | c.3430-4G>T | Splice Region (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ADD1 | c.1502A>T p.E501V | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AKR1C8P | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ALB | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 85/151 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ANAPC7 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP24 | c.577G>A p.G193R (on ENST00000395184 / NM_001025616.3; = p.G100R on NM_031305.3) | Missense Mutation (SNP) | VAF 80/153 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL3 | c.3040-1G>A p.X1014_splice | Splice Site (SNP) | VAF 12/15 reads (80%) | called by muse, mutect2
- ATAD2 | c.3266T>A p.I1089N | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP10D | c.2577G>T p.R859S | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA1I | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 116/155 reads (75%) | SIFT tolerated (0.45); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CAMK4 | c.387G>A p.R129= | Splice Region (SNP) | VAF 54/101 reads (53%) | called by muse, mutect2, varscan2
- CARMIL1 | c.1140C>A p.D380E | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC93 | c.1337C>A p.A446E | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCNA1 | c.1291C>T p.L431F | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CLCA4 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN3 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.208); called by muse, mutect2
- COLGALT2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIP2C | c.2945_2946insA p.T983Hfs*30 | Frame Shift Ins (INS) | VAF 40/189 reads (21%) | called by mutect2, pindel, varscan2
- DNAH17 | c.8415T>G p.S2805R | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUOX2 | c.2017C>A p.Q673K | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPG5 | c.2408A>G p.Y803C | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FAT3 | c.1873del p.Y625Ifs*2 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- FRAS1 | c.11620G>A p.G3874R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRG3 | c.524T>A p.L175Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GATM | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GBA2 | c.2062T>A p.C688S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GLB1L2 | c.340A>C p.N114H | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2
- GLB1L3 | c.418A>C p.N140H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- GPR108 | c.44C>A p.A15E | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- GPR34 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GPR83 | c.970_984del p.N324_F328del | In Frame Del (DEL) | VAF 41/236 reads (17%) | called by mutect2, pindel, varscan2
- GUCY1A2 | c.1808T>G p.V603G | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC1 | c.4208G>A p.R1403K | Missense Mutation (SNP) | VAF 164/236 reads (69%) | SIFT tolerated (0.49); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IL10RA | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- KCNH5 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- KLHDC7A | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT83 | c.905A>T p.Y302F | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- LIG4 | c.1588C>T p.H530Y | Missense Mutation (SNP) | VAF 123/264 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRFN2 | c.1504C>G p.L502V | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MAMLD1 | c.1939T>A p.W647R | Missense Mutation (SNP) | VAF 41/388 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- MAP3K9 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 96/168 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEGF8 | c.6136C>T p.P2046S (on ENST00000251268 / NM_001271938.2; = p.P1979S on NM_001410.3) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- MOXD1 | c.1334A>C p.Y445S | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MROH1 | c.4776G>A p.G1592= | Splice Region (SNP) | VAF 138/297 reads (46%) | called by muse, mutect2, varscan2
- MYOM2 | c.3637C>T p.L1213F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- N4BP2 | c.978C>G p.F326L | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NAA16 | c.2211G>A p.M737I | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NSUN7 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ODF2L | c.395T>G p.M132R | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- OLFM3 | c.1402C>G p.L468V (on ENST00000338858 / NM_001288821.1; = p.L448V on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR5H1 | c.151A>T p.K51* | Nonsense Mutation (SNP) | VAF 57/245 reads (23%) | called by muse, mutect2, varscan2
- PAX4 | c.994A>T p.S332C | Missense Mutation (SNP) | VAF 139/156 reads (89%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PCDHB1 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- PCSK1 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDZD4 | c.1988A>C p.D663A | Missense Mutation (SNP) | VAF 111/237 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFN2 | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 149/175 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHG4B | c.527C>T p.P176L (on ENST00000283426; = p.P532L on NM_052909.5) | Missense Mutation (SNP) | VAF 121/270 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPFIA3 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROM2 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 63/148 reads (43%) | called by muse, mutect2, varscan2
- PRPF19 | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PTPN23 | c.3850G>A p.V1284I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RBMX | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 79/274 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- RSBN1 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RSPO2 | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RTL1 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- SCRN1 | c.599_605del p.E200Gfs*32 | Frame Shift Del (DEL) | VAF 23/63 reads (37%) | called by mutect2, pindel, varscan2
- SELE | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SENP6 | c.3067C>T p.Q1023* | Nonsense Mutation (SNP) | VAF 96/186 reads (52%) | called by muse, mutect2, varscan2
- SIGLEC9 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SLC6A11 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SLCO1B1 | c.137T>A p.I46N | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SOGA3 | c.1355A>C p.H452P | Missense Mutation (SNP) | VAF 71/103 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTBN1 | c.33C>A p.N11K | Missense Mutation (SNP) | VAF 69/285 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TCEA2 | c.449T>A p.L150Q | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM102 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- TMEM177 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- TNN | c.3119C>T p.S1040F | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TSGA10 | c.1089A>T p.K363N | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTLL3 | c.477+1G>A p.X159_splice | Splice Site (SNP) | VAF 41/254 reads (16%) | called by muse, mutect2, varscan2
- TUBA4B | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- UNC80 | c.2449C>A p.R817S | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VCAN | c.2710G>T p.E904* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | called by muse, varscan2
- VCAN | c.3547G>A p.G1183R | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13D | c.2062A>G p.I688V | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- VPS13D | c.9553G>A p.V3185I | Missense Mutation (SNP) | VAF 171/394 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- WAC | c.1519C>G p.H507D | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- WWP1 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 83/371 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XPNPEP1 | c.1617T>G p.N539K | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZAN | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ZNF227 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ZNF711 | c.769G>T p.V257F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- AC100868.1 | c.1476T>G p.P492= | Silent (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- ADCY8 | c.3423G>A p.K1141= | Silent (SNP) | VAF 58/298 reads (19%) | catalogued as COSV99652665; called by muse, mutect2, varscan2
- ADGB | c.963G>A p.G321= | Silent (SNP) | VAF 49/210 reads (23%) | called by muse, mutect2, varscan2
- ADGB | c.4527G>A p.K1509= | Silent (SNP) | VAF 30/112 reads (27%) | called by muse, mutect2, varscan2
- AIMP1 | c.750A>G p.R250= | Silent (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- ANK3 | c.2751C>T p.F917= (on ENST00000280772 / NM_001320874.2; = p.F51= on NM_001149.3) | Silent (SNP) | VAF 60/99 reads (61%) | called by muse, mutect2, varscan2
- ANKRD30BL | c.540G>A p.R180= | Silent (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- BCL11B | c.1182C>T p.P394= (on ENST00000357195 / NM_001282237.2; = p.P323= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs766752148; called by muse, mutect2, varscan2
- BOC | c.1002C>T p.I334= | Silent (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2
- CEACAM4 | c.489G>A p.G163= | Silent (SNP) | VAF 39/55 reads (71%) | called by muse, mutect2, varscan2
- CES1 | c.927G>A p.Q309= | Silent (SNP) | VAF 64/217 reads (29%) | called by muse, mutect2, varscan2
- CHAT | c.1104C>T p.L368= | Silent (SNP) | VAF 45/223 reads (20%) | catalogued as rs551349781, COSV60319800; called by muse, mutect2, varscan2
- CNGB3 | c.2358C>A p.I786= | Silent (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- COLGALT2 | c.765C>T p.P255= | Silent (SNP) | VAF 49/153 reads (32%) | called by muse, mutect2, varscan2
- CSF3 | c.147G>A p.E49= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV56640795; called by muse, mutect2
- CTC1 | c.3405C>T p.D1135= | Silent (SNP) | VAF 118/138 reads (86%) | catalogued as rs755058193; called by muse, mutect2, varscan2
- CYP1A2 | c.780C>T p.F260= | Silent (SNP) | VAF 74/106 reads (70%) | catalogued as COSV100673882; called by muse, mutect2, varscan2
- DNAH8 | c.7086G>A p.L2362= | Silent (SNP) | VAF 79/400 reads (20%) | called by muse, mutect2, varscan2
- ELFN1 | c.246C>T p.R82= | Silent (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- FGFR2 | c.789G>A p.P263= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as rs138315382; called by muse, mutect2, varscan2
- FOXP2 | c.681C>G p.L227= | Silent (SNP) | VAF 66/255 reads (26%) | called by muse, varscan2
- GPC5 | c.648G>A p.G216= | Silent (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- HCN4 | c.1893G>A p.K631= | Silent (SNP) | VAF 63/143 reads (44%) | called by muse, mutect2, varscan2
- HDAC8 | c.675C>T p.Y225= | Silent (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- HMCN1 | c.4320T>A p.S1440= | Silent (SNP) | VAF 39/229 reads (17%) | called by muse, mutect2, varscan2
- HOXB2 | c.300G>A p.E100= | Silent (SNP) | VAF 58/321 reads (18%) | called by muse, mutect2, varscan2
- IRF5 | c.1152G>A p.K384= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as rs961082732, COSV50860914, COSV50861104; called by muse, mutect2, varscan2
- KBTBD11 | c.847C>T p.L283= | Silent (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- KCP | c.435C>T p.Y145= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs909358331, COSV52822328; called by muse, mutect2, varscan2
- KSR2 | c.1929G>A p.R643= | Silent (SNP) | VAF 40/73 reads (55%) | catalogued as COSV56664620; called by muse, mutect2, varscan2
- LAMA5 | c.8622C>T p.F2874= | Silent (SNP) | VAF 44/218 reads (20%) | catalogued as rs141347564; ClinVar: likely benign; called by muse, varscan2
- LARP1 | c.60C>T p.F20= | Silent (SNP) | VAF 94/118 reads (80%) | catalogued as COSV60430163; called by muse, mutect2, varscan2
- MARK3 | c.1896C>T p.N632= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as rs902962601; called by muse, mutect2, varscan2
- MTOR | c.1653C>T p.P551= | Silent (SNP) | VAF 42/239 reads (18%) | catalogued as COSV63872750; called by muse, mutect2, varscan2
- MUC4 | c.12285C>T p.T4095= | Silent (SNP) | VAF 76/115 reads (66%) | catalogued as rs559831827; called by muse, mutect2, varscan2
- MYPN | c.3945G>A p.V1315= | Silent (SNP) | VAF 164/293 reads (56%) | catalogued as rs267602553; called by muse, mutect2, varscan2
- NOMO1 | c.3300C>T p.F1100= | Silent (SNP) | VAF 44/190 reads (23%) | called by muse, mutect2, varscan2
- NPC2 | c.405C>T p.N135= | Silent (SNP) | VAF 190/341 reads (56%) | called by muse, mutect2, varscan2
- NPY1R | c.1154G>A p.*385= | Silent (SNP) | VAF 19/28 reads (68%) | called by muse, mutect2, varscan2
- NR4A2 | c.639G>A p.V213= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- NYAP2 | c.99C>A p.G33= | Silent (SNP) | VAF 53/218 reads (24%) | called by muse, mutect2, varscan2
- OR2H2 | c.78C>T p.F26= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs749678413; called by muse, mutect2
- OR7A10 | c.189C>T p.L63= | Silent (SNP) | VAF 32/181 reads (18%) | catalogued as rs202143392, COSV50166131; called by muse, mutect2, varscan2
- PARP8 | c.1803C>T p.N601= | Silent (SNP) | VAF 70/159 reads (44%) | called by muse, mutect2, varscan2
- PMFBP1 | c.480G>A p.A160= | Silent (SNP) | VAF 29/165 reads (18%) | catalogued as rs373109383; called by muse, mutect2, varscan2
- PNMA8A | c.579G>A p.G193= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs1262977835; called by muse, mutect2, varscan2
- PRICKLE2 | c.2065C>T p.L689= (on ENST00000295902; = p.L633= on NM_198859.4) | Silent (SNP) | VAF 95/186 reads (51%) | catalogued as rs576746551; called by muse, mutect2, varscan2
- PRPH | c.1167G>A p.L389= | Silent (SNP) | VAF 52/82 reads (63%) | called by muse, mutect2, varscan2
- SACS | c.576T>C p.I192= | Silent (SNP) | VAF 78/344 reads (23%) | catalogued as rs1314146678; called by muse, mutect2, varscan2
- SCN1A | c.1470T>C p.S490= | Silent (SNP) | VAF 150/297 reads (51%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.3933C>T p.F1311= | Silent (SNP) | VAF 39/253 reads (15%) | called by muse, mutect2, varscan2
- SLC22A18 | c.927G>A p.R309= | Silent (SNP) | VAF 72/221 reads (33%) | called by muse, mutect2, varscan2
- SLC25A13 | c.942A>T p.S314= | Silent (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- SPATA21 | c.534G>A p.R178= | Silent (SNP) | VAF 99/250 reads (40%) | called by muse, mutect2, varscan2
- TGIF2LX | c.165A>G p.G55= | Silent (SNP) | VAF 107/122 reads (88%) | called by muse, mutect2, varscan2
- TMEM236 | c.555C>T p.N185= | Silent (SNP) | VAF 352/840 reads (42%) | catalogued as rs1446749397; called by muse, mutect2, varscan2
- USP34 | c.5370C>T p.L1790= | Silent (SNP) | VAF 119/260 reads (46%) | catalogued as rs757783347; called by muse, mutect2, varscan2
- WDR81 | c.1572C>T p.F524= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs1464979783; called by muse, mutect2, varscan2
- ABHD12 | c.1029+20T>G | Intron (SNP) | VAF 106/474 reads (22%) | called by muse, mutect2, varscan2
- AC125421.1 | n.325-207C>T | Intron (SNP) | VAF 116/219 reads (53%) | called by muse, mutect2, varscan2
- ADAM21P1 | n.1202G>A | RNA (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- ASIC4 | c.1018+526C>T | Intron (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- BMP7 | c.1036-22C>T | Intron (SNP) | VAF 103/245 reads (42%) | called by muse, mutect2, varscan2
- CCL4L2 | c.191+73G>A | Intron (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- DNAH14 | c.1032+140C>T | Intron (SNP) | VAF 54/181 reads (30%) | catalogued as rs1335581482, COSV100835884; called by muse, mutect2, varscan2
- DST | c.4297-2865C>T | Intron (SNP) | VAF 42/192 reads (22%) | called by muse, mutect2, varscan2
- EHMT2 | c.43-10C>T | Intron (SNP) | VAF 8/10 reads (80%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009623 G>A | 5'Flank (SNP) | VAF 29/84 reads (35%) | catalogued as rs1431085241; called by muse, mutect2, varscan2
- HBD | chr11:5232764 C>T | 3'Flank (SNP) | VAF 39/180 reads (22%) | catalogued as rs567792872; called by muse, mutect2, varscan2
- HSP90AA4P | n.2085T>C | RNA (SNP) | VAF 94/103 reads (91%) | called by muse, mutect2, varscan2
- LRRC74A | c.217+706T>C | Intron (SNP) | VAF 61/184 reads (33%) | catalogued as rs1044980619; called by muse, mutect2, varscan2
- MIR300 | n.80C>T | RNA (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- NELL2 | c.335+33C>T | Intron (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- NFYC | c.828+18A>G | Intron (SNP) | VAF 69/168 reads (41%) | called by muse, mutect2, varscan2
- NREP | c.-23C>T | 5'UTR (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- RNF213 | c.10579-27G>A | Intron (SNP) | VAF 50/171 reads (29%) | catalogued as rs745722686; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43300593 G>A | 5'Flank (SNP) | VAF 35/48 reads (73%) | called by muse, mutect2, varscan2
- SCP2D1 | chr20:18809961 C>T | 5'Flank (SNP) | VAF 27/166 reads (16%) | called by muse, mutect2, varscan2
- SREBF1 | c.*712C>T | 3'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- SRGAP3 | c.*45C>T | 3'UTR (SNP) | VAF 22/157 reads (14%) | catalogued as rs1374781053; called by muse, varscan2
- STX8 | chr17:9575840 C>T | 5'Flank (SNP) | VAF 57/69 reads (83%) | catalogued as rs573546672; called by muse, mutect2, varscan2
- UNG | c.-8G>T | 5'UTR (SNP) | VAF 68/348 reads (20%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:23490996 G>A | 3'Flank (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2, varscan2
- ZNF304 | c.-17C>T | 5'UTR (SNP) | VAF 26/95 reads (27%) | catalogued as rs1226968807; called by muse, mutect2, varscan2
